Somatic mutation profile of tumor specimen TCGA-AR-A1AQ-01A (aliquot TCGA-AR-A1AQ-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-AR-A1AQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9767d1c-cfad-4a5d-92e8-4d963225d233.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AQ-10A (Blood Derived Normal), aliquot TCGA-AR-A1AQ-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96a5e1e9-e395-4d8d-961c-9fe54621099d

The open-access MAF lists 38 somatic variants for this specimen: 34 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 21, Frame Shift Del 4, Silent 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 190/476 reads (40%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC8 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV56857747; called by muse, mutect2
- ATG2B | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.191); catalogued as COSV55892089; called by muse, mutect2, varscan2
- ATN1 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63113024; called by muse, mutect2, varscan2
- BACH1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV54521167; called by muse, mutect2, varscan2
- CCPG1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60527761; called by muse, mutect2, varscan2
- CNPY3 | c.667G>C p.G223R | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.11); catalogued as COSV65710056; called by muse, mutect2, varscan2
- COL2A1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100477551; called by muse, mutect2
- CUL9 | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs374310005; called by muse, mutect2, varscan2
- DERL1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 8/264 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV99418748; called by muse, mutect2
- DHX36 | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 24/316 reads (8%) | catalogued as rs143454337, COSV100273596, COSV100273973; called by muse, mutect2
- DNAH7 | c.5596C>T p.R1866* | Nonsense Mutation (SNP) | VAF 97/215 reads (45%) | catalogued as rs762961022, COSV100414182, COSV56785723; called by muse, mutect2, varscan2
- FLII | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV58948053; called by muse, mutect2, varscan2
- FLT1 | c.3040T>C p.S1014P | Missense Mutation (SNP) | VAF 92/163 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56742913; called by muse, mutect2, varscan2
- FNIP1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV57200669; called by muse, mutect2, varscan2
- LRRC41 | c.1698del p.G567Vfs*12 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as COSV58442443; called by mutect2, pindel, varscan2
- MYO18A | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62873221; called by muse, mutect2, varscan2
- NWD1 | c.4250T>C p.L1417P | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60351671; called by muse, mutect2, varscan2
- OR52N1 | c.147C>A p.Y49* | Nonsense Mutation (SNP) | VAF 10/163 reads (6%) | catalogued as COSV100398733; called by muse, mutect2
- PARD3 | c.3714C>G p.D1238E | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.99); catalogued as COSV61068586; called by muse, mutect2, varscan2
- PIP5K1C | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.312); catalogued as rs145403606, COSV58955923; called by muse, mutect2, varscan2
- PLD5 | c.933G>A p.S311= (on ENST00000442594; = p.S249= on NM_001195811.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 49/227 reads (22%) | catalogued as rs1344302255, COSV100138191, COSV59167797; called by muse, mutect2, varscan2
- PREX1 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1458758830, COSV64256845; called by muse, mutect2, varscan2
- RB1 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 89/195 reads (46%) | catalogued as CM034898, COSV57294725, COSV57317489; called by muse, mutect2, varscan2
- RNF144A | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 178/413 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57985269; called by muse, mutect2, varscan2
- SEMA3A | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 91/392 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV54887778, COSV54887914; called by muse, mutect2, varscan2
- SPDEF | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776586725, COSV55062503; called by muse, mutect2, varscan2
- SPTA1 | c.4007C>T p.A1336V | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV63759322; called by muse, mutect2, varscan2
- STIM1 | c.776A>G p.H259R | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.852); catalogued as rs1359363776, COSV56160633; called by muse, mutect2, varscan2
- ZBTB33 | c.2014_2015insTA p.Y672Lfs*6 | Frame Shift Ins (INS) | VAF 5/25 reads (20%) | catalogued as COSV58535136; called by mutect2, pindel, varscan2
- APOBEC2 | c.432_433dup p.L145Pfs*23 | Frame Shift Ins (INS) | VAF 18/151 reads (12%) | called by mutect2, pindel, varscan2
- WWP2 | c.2415del p.V806Sfs*48 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- GAB4 | c.609G>A p.P203= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs545946229, COSV68753009; called by muse, mutect2, varscan2
- GALNT3 | c.798A>G p.T266= | Silent (SNP) | VAF 109/252 reads (43%) | catalogued as COSV67062509; called by muse, mutect2, varscan2
- MALT1 | c.2010C>A p.T670= | Silent (SNP) | VAF 18/350 reads (5%) | catalogued as COSV100618881; called by muse, mutect2
- MUC16 | c.12981C>T p.V4327= | Silent (SNP) | VAF 83/311 reads (27%) | catalogued as COSV67493842; called by muse, mutect2, varscan2
